Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7959, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7959-01A (Primary Tumor).

[page 1 of 4]
[REDACTED] ID		Gross Description	Microscopic Description
Case ID			
[REDACTED]	[REDACTED]		

[page 2 of 4]
Diagnosis Details	Comments

[page 3 of 4]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastric resection
Tumor site: Cardia
Tumor size: 5 x 3.5 x 1.5 cm
Tumor features: None specified
Histologic type: Mucin-producing adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Serosa (visceral peritoneum)
Lymph nodes: 1/7 positive for metastasis (Intraabdominal 1/7)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Laterality

[page 4 of 4]
Excision date

McGraw-Hill

Source: NCI Genomic Data Commons file f1de7152-f761-46c3-a70a-3ba9ca1b6c7a (TCGA-BR-7959.8BA6CEEE-5887-4FC6-A78B-4214AB41973C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).